Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5690, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5690-01A (Primary Tumor).

RIGHT KIDNEY, LAPAROSCOPIC NEPHRECTOMY –

- A Side: 1
- B. Location: 1
1. Kidney (parenchyma - cortex/medulla)
2. Kidney (pelvis)
- C. Procedure: 2
1. Partial nephrectomy
2. Simple nephrectomy
3. Radical nephrectomy
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 4.2 cm
- E. Type of malignant neoplasm: 1
1. Renal cell carcinoma, clear cell type
(includes non-papillary granular cell RCC)
2. Renal cell carcinoma, chromophil cell type
(papillary RCC, no clear cell component)
3. Renal cell carcinoma, chromophobe cell type
4. Renal cell carcinoma, oncocytic
5. Renal cell carcinoma, sarcomatoid
6. Collecting duct carcinoma
7. Urothelial carcinoma, TCCa
(non-invasive)
8. Urothelial carcinoma, TCCa
(invasive ± in-situ)
9. Urothelial carcinoma, squamous carcinoma
10. Urothelial carcinoma, adenocarcinoma
- F. Histologic grade
- F1. Fuhrman grade (for RCC; grades 1-4): 1
- F2. Ash grade (grade 1-4): N/A
- F3. WHO grade (grade 1-3): N/A (for TCCa)
- F4. [REDACTED]
1. LMP 2. LG 3. HG
- F5. Other malignant neoplasms (grades 1-3): N/A
- G. Non-neoplastic and other conditions:
1. Glomerulopathy
2. Interstitial nephritis
3. Pyelonephritis
4. Nephrolithiasis
5. Papillary necrosis
6. Chronic parenchymal disease
7. Other
- H. Margins of resection: 2
- I. Mitotic activity: 0 per 10 high power fields
- J. Angiolymphatic invasion
- J1. Macroscopic (e.g., renal vein thrombus): 2
- J2. Microscopic: 2
- K. Number of positive lymph nodes: N/A
- L. Total number of lymph nodes examined: 0
- M. Extracapsular spread of lymph node metastases: N/A
1. Yes 2. No
- N. Adrenal gland:
- N1. Present 2
- N2. Involvement by renal neoplasm: 3
- N3. Other adrenal pathology: 3
- O. TNM stage: T 1b N x M x
2. Left
3. Ureter
4. Kidney and ureter
4. Uretectomy
5. Other
11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
12. Urothelial carcinoma, mixed
13. Juxtaglomerular cell tumor
14. Wilms' tumor
15. Rhabdoid tumor
16. Clear cell sarcoma
17. Congenital mesoblastic nephroma
18. Sarcoma (non-clear cell)
19. Lymphoma/leukemia
20. Other
1. Positive 2. Negative
1. Positive 2. Negative
1. Positive 2. Negative
1. Yes 2. No 3. Not Applicable
1. Yes 2. No 3. Not applicable

Source: NCI Genomic Data Commons file 029c62ea-0204-4af6-9695-e082d40977fe (TCGA-B0-5690.E29C0AC2-28DF-4C36-8A4B-E7A2D038AB11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).